Somatic mutation profile of tumor specimen TCGA-B5-A11F-01A (aliquot TCGA-B5-A11F-01A-11D-A10M-09) from TCGA case TCGA-B5-A11F, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 55.2 years (20,171 days).
Specimen TCGA-B5-A11F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09d248af-b56b-42ca-9872-1d05055f95e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11F-10A (Blood Derived Normal), aliquot TCGA-B5-A11F-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f33bd631-e90f-4f29-b52e-d487f6be7452

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1060501244, CM041747, COSV55728376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1610A>C p.Y537S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52782924, COSV52783938; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.722T>C p.F241S | Missense Mutation (SNP) | VAF 81/89 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs121909240, CM051215, COSV64294827; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY2 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs141886153, COSV100602683; called by muse, mutect2, varscan2
- ATRN | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV53528535; called by muse, mutect2, varscan2
- CNTN5 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54316060; called by muse, mutect2, varscan2
- CNTNAP2 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62189143; called by muse, mutect2, varscan2
- COLEC12 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV68370957; called by muse, mutect2, varscan2
- DSCAML1 | c.3238C>T p.R1080W (on ENST00000321322; = p.R1020W on NM_020693.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1034319646, COSV58386656; called by muse, mutect2, varscan2
- EPHA5 | c.2628G>T p.E876D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56648407; called by muse, mutect2, varscan2
- EPHB6 | c.1099T>G p.C367G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV67418784; called by muse, mutect2, varscan2
- FARP2 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV50872022; called by muse, mutect2, varscan2
- FARSB | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs772259212, COSV56049948, COSV56053376; called by muse, mutect2, varscan2
- GPR12 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766767187, COSV67344393; called by muse, mutect2, varscan2
- ITIH5 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs749075587, COSV53667203; called by muse, mutect2, varscan2
- KNDC1 | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs375417854; called by muse, mutect2, varscan2
- MECOM | c.1585T>C p.S529P (on ENST00000468789 / NM_001105078.4; = p.S717P on NM_004991.4) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52965690; called by muse, mutect2
- OR4K15 | c.995C>A p.P332H (on ENST00000305051; = p.P308H on NM_001005486.1) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.592); catalogued as COSV59301647; called by muse, mutect2, varscan2
- PIK3R1 | c.1735_1745+2del p.X579_splice (on ENST00000521381 / NM_181523.3; = p.X309_splice on NM_181504.4) | Splice Site (DEL) | VAF 52/151 reads (34%) | catalogued as COSV57131300; called by mutect2, pindel, varscan2
- PLXNB2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63782132; called by muse, mutect2, varscan2
- PRLH | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs147108124, COSV99382211; called by muse, mutect2, varscan2
- PRX | c.4207G>A p.V1403I | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as rs139051512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SECTM1 | c.745T>C p.*249Qext*151 | Nonstop Mutation (SNP) | VAF 120/266 reads (45%) | catalogued as rs902845140, COSV53939593; called by muse, mutect2, varscan2
- SESTD1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100090984, COSV58931471; called by muse, mutect2, varscan2
- SIN3A | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64583197; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 104/261 reads (40%) | PolyPhen probably damaging (0.996); catalogued as rs193112516, COSV52535696; called by muse, mutect2, varscan2
- TKTL2 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs961660795, COSV54918377; called by muse, mutect2, varscan2
- UCK2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 198/274 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV63315551; called by muse, mutect2, varscan2
- VIT | c.1741G>A p.A581T (on ENST00000389975 / NM_001177969.1; = p.A596T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.483); catalogued as rs200598704, COSV64896862; called by muse, mutect2, varscan2
- ZNF292 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV60540208; called by muse, mutect2, varscan2
- ZNF804A | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs1300852164, COSV56433664; called by muse, mutect2, varscan2
- ARID5B | c.1370del p.N457Mfs*22 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | called by mutect2, pindel, varscan2
- POTEM | c.1446del p.E483Nfs*12 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- CADPS2 | c.978G>A p.S326= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs772232660, COSV57348365; called by muse, mutect2, varscan2
- KCNA5 | c.279C>A p.P93= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs765468241, COSV52906394, COSV52908133; called by muse, mutect2, varscan2
- MECOM | c.1587G>A p.S529= (on ENST00000468789 / NM_001105078.4; = p.S717= on NM_004991.4) | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as rs368981948, COSV52965676; called by muse, mutect2
- NMUR2 | c.882G>A p.V294= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV54919893; called by muse, mutect2, varscan2
- PIGW | c.21G>A p.K7= | Silent (SNP) | VAF 103/523 reads (20%) | catalogued as rs771108238; called by muse, mutect2, varscan2
- RAP1B | c.48G>A p.K16= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV51668805; called by muse, mutect2, varscan2
- ROBO1 | c.4815C>T p.S1605= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs1178919329, COSV71395002, COSV71397870; called by muse, mutect2, varscan2
- TACR2 | c.480C>T p.L160= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs970785006, COSV64822323; called by muse, mutect2, varscan2
- SSPOP | n.7334G>A | RNA (SNP) | VAF 75/172 reads (44%) | catalogued as rs780901933, COSV50487746; called by muse, mutect2, varscan2
